Somatic mutation profile of tumor specimen BA2763D (aliquot aq-BA2763D) from BEATAML1.0 case 2384, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.1 years (26,352 days).
Specimen BA2763D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2fa221a0-3a4b-4723-9ba1-f75775df38da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2349D (Solid Tissue Normal), aliquot aq-BA2349D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/748ed2a0-27a8-4281-96e0-b84242cae0e7

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 4, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>A p.R132S | Missense Mutation (SNP) | VAF 42/148 reads (28%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SRSF2 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 21/54 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.57); PolyPhen benign (0.398); catalogued as rs751713049, CM1511359, COSV57969809, COSV57969816, COSV57969830; called by muse, mutect2, varscan2
- ALX3 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757293052, COSV63928785; called by muse, mutect2, varscan2
- MCM9 | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as rs568372543; called by muse, mutect2, varscan2
- POLQ | c.572T>C p.I191T | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138477339; called by muse, mutect2, varscan2
- CCDC93 | c.1121T>A p.I374K | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GCNT2 | c.536C>A p.A179D | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.487); called by muse, mutect2
- KATNAL1 | c.794G>A p.C265Y | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH18 | c.1567T>A p.S523T | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZC4H2 | c.472G>T p.A158S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.751); called by muse, mutect2
- PITX1 | c.570G>A p.A190= | Silent (SNP) | VAF 29/220 reads (13%) | called by muse, mutect2, varscan2
- PRRC2C | c.7932T>C p.A2644= (on ENST00000367742; = p.A2642= on NM_015172.4) | Silent (SNP) | VAF 9/108 reads (8%) | catalogued as rs1053585855; called by muse, mutect2
- FSTL4 | c.1340-122G>T | Intron (SNP) | VAF 12/21 reads (57%) | catalogued as rs1296161512; called by muse, mutect2, varscan2
- MYH11 | c.5172-13G>T | Intron (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- NDE1 | c.1030+2884G>C | Intron (SNP) | VAF 29/138 reads (21%) | called by muse, mutect2, varscan2
- TNS2 | c.223-42C>A | Intron (SNP) | VAF 54/165 reads (33%) | called by muse, mutect2, varscan2
